Somatic mutation profile of tumor specimen ALCH-B1JI-TTP1-A (aliquot ALCH-B1JI-TTP1-A-2-0-D-A76C-36) from ALCHEMIST case ALCH-B1JI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.5 years (16,971 days).
Specimen ALCH-B1JI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a529e81-fa3d-40b2-9c4f-c3fa51a422ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JI-NB1-A (Blood Derived Normal), aliquot ALCH-B1JI-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f122ce1-4544-4740-87a3-3ce2a0c4c828

The open-access MAF lists 277 somatic variants for this specimen: 185 protein-altering or splice-affecting, 61 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 61, Nonsense Mutation 10, 5'UTR 8, Intron 8, RNA 7, 3'UTR 6, Splice Site 5, Frame Shift Del 4, Splice Region 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 35/239 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.533A>C p.H178P | Missense Mutation (SNP) | VAF 42/334 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526004, COSV52689182, COSV53235050, COSV53281657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADL | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as COSV52053850; called by muse, mutect2
- ACE2 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs865852627, COSV104384490; called by muse, mutect2
- ACKR1 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100929482; called by muse, mutect2, varscan2
- ADAMTS13 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 55/562 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1564407799; called by muse, mutect2, varscan2
- ADAMTS6 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.049); catalogued as COSV66857021; called by muse, mutect2
- ALDH8A1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV55640284, COSV55641714; called by muse, mutect2
- ARHGAP36 | c.1282G>T p.V428L | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs759360772; called by mutect2, varscan2
- ASTN1 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1412327564; called by muse, mutect2, varscan2
- BCOR | c.3586G>T p.V1196L | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60715118; called by muse, mutect2
- C7orf26 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs774340404; called by muse, mutect2, varscan2
- CACNA1E | c.1953C>A p.F651L | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62392608; called by muse, mutect2
- COL4A5 | c.546+1G>T p.X182_splice | Splice Site (SNP) | VAF 22/186 reads (12%) | catalogued as CS961507; called by muse, varscan2
- CR1 | c.5311+1G>C p.X1771_splice | Splice Site (SNP) | VAF 30/246 reads (12%) | catalogued as COSV65458183; called by muse, mutect2, varscan2
- DEFB115 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.084); catalogued as rs1203888527, COSV68723545; called by muse, mutect2
- ENTHD1 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321464; called by muse, mutect2, varscan2
- FAM47C | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 90/701 reads (13%) | catalogued as COSV63725612; called by muse, varscan2
- FAT3 | c.2670C>A p.D890E | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.501); catalogued as rs1377497566, COSV99963641; called by muse, mutect2, varscan2
- FAT3 | c.7384G>T p.E2462* | Nonsense Mutation (SNP) | VAF 16/196 reads (8%) | catalogued as COSV53124800, COSV53161031; called by muse, mutect2
- FLRT2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs1416415206, COSV58147096; called by muse, mutect2
- GIMAP8 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56231181, COSV56233690; called by muse, mutect2
- GPR156 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs906074777; called by muse, mutect2
- HSD3B1 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs148057809, COSV52489580; called by muse, mutect2
- ITGA8 | c.1158C>G p.F386L | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV65226540, COSV65227301; called by muse, mutect2, varscan2
- KCNU1 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV67756210; called by muse, mutect2
- KDR | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV99817949; called by muse, mutect2
- KIAA1549 | c.3946G>C p.V1316L | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99649665; called by muse, mutect2
- KIF6 | c.1227C>G p.D409E | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54700526; called by muse, mutect2
- LAMA1 | c.4972G>C p.A1658P | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.457); catalogued as COSV67545769; called by muse, mutect2, varscan2
- LCE3E | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 64/688 reads (9%) | catalogued as rs753201269; called by muse, mutect2
- MED12L | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV99852103; called by muse, mutect2
- NCAPH | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53638835; called by muse, mutect2
- NEGR1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV100161909; called by muse, mutect2, varscan2
- NEU4 | c.553G>C p.E185Q (on ENST00000391969 / NM_001167602.3; = p.E197Q on NM_080741.4) | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as rs1265232152; called by muse, mutect2
- NLRP3 | c.1659C>A p.S553R | Missense Mutation (SNP) | VAF 88/668 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs200224266, COSV60230830; called by muse, mutect2, varscan2
- NPAS3 | c.1897C>A p.P633T (on ENST00000356141 / NM_001164749.2; = p.P601T on NM_022123.3) | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV60833763; called by muse, mutect2
- NXPE4 | c.989G>C p.C330S (on ENST00000375478 / NM_001077639.2; = p.C46S on NM_017678.3) | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376776586; called by muse, mutect2, varscan2
- OR10G4 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100304699; called by muse, mutect2
- OR2H2 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63544561; called by muse, mutect2, varscan2
- OR52N2 | c.440del p.G147Vfs*6 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | catalogued as COSV100396073; called by mutect2, pindel
- OR6V1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as rs749931454; called by muse, mutect2
- OR9K2 | c.700C>A p.P234T (on ENST00000305377; = p.P212T on NM_001005243.1) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.55); PolyPhen probably damaging (1); catalogued as COSV59531634; called by muse, mutect2, varscan2
- P2RY4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs778002771; called by muse, mutect2, varscan2
- PCDH11X | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); catalogued as COSV100015633, COSV53510739; called by muse, mutect2
- PCDHA6 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100972421; called by muse, mutect2
- PCLO | c.13372G>T p.G4458C | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs763214769; called by muse, mutect2
- PDZD11 | c.231G>A p.V77= | Splice Region (SNP) | VAF 18/206 reads (9%) | catalogued as rs893734188; called by muse, mutect2
- PIDD1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs533514354, COSV61706735; called by muse, mutect2, varscan2
- PORCN | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 26/499 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as CM096007, COSV100400261; called by muse, mutect2
- RELN | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1446098977; called by muse, mutect2
- RHOBTB1 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 44/433 reads (10%) | catalogued as COSV61960194; called by muse, mutect2, varscan2
- RTEL1 | c.2369A>G p.K790R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs200521508; called by muse, mutect2, varscan2
- SCN7A | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV69274565; called by muse, mutect2
- SERPINB13 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs769456268; called by muse, mutect2, varscan2
- SLC13A3 | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1568929497, COSV99287428; called by muse, mutect2
- SLCO1B1 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV57016831; called by muse, mutect2, varscan2
- STOX1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373094820; called by muse, mutect2
- TMEM39B | c.383T>C p.M128T | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1285947393; called by muse, mutect2
- TSHZ3 | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53674652; called by muse, mutect2, varscan2
- WNK2 | c.2677G>C p.G893R | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV52938703; called by muse, mutect2
- YDJC | c.103A>C p.T35P | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1555888063; called by muse, mutect2, varscan2
- ZNF521 | c.3283G>T p.G1095C | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV64123210, COSV64129616; called by muse, mutect2
- ZNF658 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs560970467; called by muse, mutect2
- ZNF716 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV70783259; called by muse, mutect2
- ABCB6 | c.2184C>G p.S728R | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC11 | c.1028G>C p.S343T | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2
- ADGRB1 | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRL3 | c.4465C>A p.L1489I (on ENST00000506720 / NM_001322402.2; = p.L1378I on NM_015236.6) | Missense Mutation (SNP) | VAF 51/503 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- AHI1 | c.2000A>T p.H667L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- ANHX | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 67/538 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ANKRD55 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO2 | c.1387G>T p.G463C (on ENST00000356134 / NM_001278597.3; = p.G467C on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2
- ASTN1 | c.1524G>A p.G508= | Splice Region (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- ATP10A | c.2768G>A p.C923Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- BIRC3 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- BRSK1 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CACNA1E | c.3361C>G p.R1121G | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACYBP | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- CADPS | c.1615T>A p.W539R | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CALY | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 42/459 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CARD6 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPERG | c.3137G>T p.C1046F | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC120 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- CCDC65 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- CDK15 | c.225T>G p.S75R (on ENST00000652192 / NM_001366386.2; = p.S24R on NM_139158.2) | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CEBPE | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CFAP46 | c.6466C>A p.Q2156K | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CNGB1 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 27/480 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- CNTNAP3 | c.1667G>T p.C556F | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL22A1 | c.4247C>A p.P1416H | Missense Mutation (SNP) | VAF 17/621 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A3 | c.4361A>T p.H1454L | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- CYFIP1 | c.651T>A p.H217Q | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CYP26B1 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CYP3A4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 38/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP7B1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DGKI | c.596T>A p.V199D | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- DNAH3 | c.6850G>T p.G2284W | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUSP6 | c.859T>A p.C287S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EFCAB8 | c.697A>C p.K233Q | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- ELAPOR2 | c.2685G>T p.Q895H (on ENST00000450689 / NM_001142749.3; = p.Q728H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EPHB6 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.125); called by muse, mutect2
- ERCC3 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 58/683 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ERVW-1 | c.1556C>A p.P519H | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- FAM170B | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FAT3 | c.13471del p.Q4491Rfs*38 | Frame Shift Del (DEL) | VAF 88/716 reads (12%) | called by mutect2, pindel*, varscan2
- FLRT2 | c.1044G>T p.M348I | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- GPHN | c.1282G>T p.E428* (on ENST00000315266 / NM_001377519.1; = p.E461* on NM_020806.5) | Nonsense Mutation (SNP) | VAF 17/326 reads (5%) | called by muse, mutect2
- GPX5 | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRIK4 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GSC | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HEATR5A | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, varscan2
- HMCN2 | c.11509G>T p.G3837C | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFI6 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- IGKV2D-24 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 38/589 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- INTS1 | c.-42+2T>A | Splice Site (SNP) | VAF 23/200 reads (12%) | called by muse, mutect2, varscan2
- IRX4 | c.953A>C p.E318A | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- KCNA4 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KLHL1 | c.1828G>T p.G610* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2
- KRTAP5-7 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 41/496 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- LGR5 | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LRRC3B | c.677G>T p.R226M | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRTM4 | c.1463A>G p.Y488C | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUZP1 | c.1627G>C p.G543R | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- MMRN2 | c.1096C>G p.P366A | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2
- MUC16 | c.7094C>A p.S2365* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- MYO5B | c.4525A>G p.I1509V | Missense Mutation (SNP) | VAF 70/514 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7B | c.1465T>A p.Y489N | Missense Mutation (SNP) | VAF 69/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NELL1 | c.2349G>A p.M783I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2
- NES | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTRK3 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NUTM2A | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 68/960 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OLIG2 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- OPRM1 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2
- OR13C8 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 30/559 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OR2T12 | c.378C>G p.H126Q | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OR5D16 | c.168dup p.L57Ifs*36 | Frame Shift Ins (INS) | VAF 16/146 reads (11%) | called by mutect2, pindel
- OR5D18 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2
- OR6V1 | c.803T>G p.V268G | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2
- OTOF | c.*17+1G>T | Splice Site (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- PAPPA | c.2554G>T p.G852C | Missense Mutation (SNP) | VAF 14/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB14 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); called by muse, mutect2
- PDE6C | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PNPLA8 | c.734A>T p.K245I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEF | c.2801C>A p.S934Y | Missense Mutation (SNP) | VAF 60/741 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- POTEI | c.2801C>A p.S934Y | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- PRDM2 | c.2373G>T p.E791D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.219); called by muse, mutect2
- PRTG | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCHD1 | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 83/458 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAB2B | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2
- RAB2B | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- RBP3 | c.2658C>A p.S886R | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- RBPJ | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- REV1 | c.2354C>G p.T785S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); called by muse, mutect2
- RFX3 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2
- RGSL1 | c.1124G>T p.C375F | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- RIMBP2 | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RREB1 | c.3027G>C p.Q1009H | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2
- SCN7A | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SERTM1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 33/357 reads (9%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); called by muse, mutect2
- SLC15A3 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SLC5A7 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- SLC6A5 | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- SLITRK4 | c.548T>A p.L183Q | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOHLH1 | c.689del p.P230Qfs*9 | Frame Shift Del (DEL) | VAF 20/195 reads (10%) | called by mutect2, pindel, varscan2
- SPATA31A6 | c.3690G>T p.Q1230H | Missense Mutation (SNP) | VAF 41/516 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2
- SPIN2A | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SRRM2 | c.6898G>T p.A2300S | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); called by muse, mutect2
- ST6GAL2 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 21/196 reads (11%) | PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- THEGL | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- THRA | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2
- TIMM44 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- TMEM132C | c.1867G>T p.V623L | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- TNR | c.3794G>T p.G1265V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC18 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- TOPBP1 | c.3964G>T p.V1322L | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- UGT2B28 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- UNC93B1 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP33 | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- VWA3A | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZEB2 | c.1130A>T p.K377I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF160 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF37A | c.456del p.A154Lfs*75 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel, varscan2
- ZNF658 | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.206); called by muse, mutect2
- ZYX | c.1594A>T p.M532L | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AEBP1 | c.819C>A p.P273= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- ATXN7L2 | c.1548G>T p.V516= | Silent (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- BMPR2 | c.21G>C p.R7= | Silent (SNP) | VAF 68/650 reads (10%) | catalogued as CD115416, CX061552; called by muse, mutect2
- BRSK1 | c.1770G>T p.L590= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- CCDC191 | c.1656C>T p.F552= | Silent (SNP) | VAF 49/469 reads (10%) | called by muse, mutect2, varscan2
- CD200R1L | c.240C>A p.A80= | Silent (SNP) | VAF 21/372 reads (6%) | called by muse, mutect2
- CDC20B | c.789G>T p.G263= | Silent (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- CDH12 | c.2238C>A p.S746= | Silent (SNP) | VAF 33/498 reads (7%) | catalogued as COSV66385669; called by muse, mutect2
- CLNK | c.885C>T p.F295= | Silent (SNP) | VAF 16/232 reads (7%) | catalogued as rs201306121; called by muse, mutect2
- CNGA4 | c.945G>A p.K315= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, varscan2
- CNTFR | c.48C>A p.A16= | Silent (SNP) | VAF 28/351 reads (8%) | called by muse, mutect2
- COL3A1 | c.1617C>A p.P539= | Silent (SNP) | VAF 22/346 reads (6%) | catalogued as rs141091206; ClinVar: likely benign; called by muse, mutect2
- CRYBG1 | c.4998G>A p.L1666= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- CSMD2 | c.1591C>A p.R531= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as COSV53904504, COSV53915786; called by muse, mutect2
- DCHS1 | c.867T>A p.A289= | Silent (SNP) | VAF 26/419 reads (6%) | catalogued as COSV55035096; called by muse, mutect2
- DLG3 | c.2085C>A p.G695= (on ENST00000374360 / NM_021120.4; = p.G390= on NM_020730.3) | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV52084799; called by muse, mutect2, varscan2
- DLGAP2 | c.480C>T p.T160= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as rs200199242; called by muse, mutect2
- DNAH10 | c.1059G>A p.A353= (on ENST00000409039; = p.A292= on NM_207437.3) | Silent (SNP) | VAF 48/362 reads (13%) | catalogued as rs371503919; called by muse, mutect2, varscan2
- ELP1 | c.3873T>A p.S1291= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- ENTR1 | c.261G>A p.P87= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as rs775534194; called by muse, mutect2
- FAM186A | c.135C>T p.F45= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as rs1272437374; called by muse, mutect2, varscan2
- FCHO1 | c.1314G>T p.P438= | Silent (SNP) | VAF 24/293 reads (8%) | called by muse, mutect2
- FREM3 | c.84G>A p.A28= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- GPHN | c.1281G>T p.V427= (on ENST00000315266 / NM_001377519.1; = p.V460= on NM_020806.5) | Silent (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- GTF3C4 | c.171C>T p.A57= | Silent (SNP) | VAF 26/355 reads (7%) | catalogued as rs750799025; called by muse, mutect2
- HIP1 | c.2922A>G p.T974= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- HOXD13 | c.438A>G p.L146= | Silent (SNP) | VAF 38/550 reads (7%) | called by muse, mutect2
- IARS2 | c.1155A>T p.A385= | Silent (SNP) | VAF 29/342 reads (8%) | called by muse, mutect2
- LHFPL4 | c.589C>T p.L197= | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- MTMR8 | c.2114G>A p.*705= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100878271; called by muse, mutect2, varscan2
- NEK3 | c.924A>T p.T308= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- NGF | c.42C>T p.I14= | Silent (SNP) | VAF 54/595 reads (9%) | catalogued as rs752800027, COSV65687643; called by muse, mutect2
- NGFR | c.1089G>A p.A363= | Silent (SNP) | VAF 43/280 reads (15%) | catalogued as rs201266194; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPEPL1 | c.1230G>T p.P410= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- OPCML | c.708C>A p.V236= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as COSV100101050, COSV59416556; called by muse, mutect2, varscan2
- OR2L3 | c.873G>T p.L291= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV63455335, COSV63455752; called by muse, mutect2, varscan2
- OR6C6 | c.153C>A p.P51= | Silent (SNP) | VAF 29/208 reads (14%) | catalogued as rs1323054824; called by muse, mutect2, varscan2
- OR9G4 | c.732C>T p.H244= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs749426357, COSV100265007; called by muse, mutect2, varscan2
- OXSM | c.1281A>G p.L427= | Silent (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- PCDHGA7 | c.135G>T p.V45= | Silent (SNP) | VAF 25/267 reads (9%) | called by muse, mutect2
- PCLO | c.6156A>G p.T2052= | Silent (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- PLXNA1 | c.5577C>T p.I1859= | Silent (SNP) | VAF 25/206 reads (12%) | catalogued as rs761797295; called by muse, mutect2, varscan2
- PLXNA4 | c.3951T>C p.Y1317= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs1189216634, COSV100322597; called by muse, mutect2
- POU3F1 | c.675G>C p.A225= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- PPFIA4 | c.1671G>A p.T557= (on ENST00000447715; = p.V547M on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/607 reads (6%) | catalogued as rs753419187, COSV55318582; called by muse, mutect2
- PTPRC | c.2289A>G p.A763= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as COSV61418931; called by muse, mutect2, varscan2
- SAMD9L | c.1968G>T p.L656= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- SCRIB | c.462G>A p.V154= | Silent (SNP) | VAF 12/340 reads (4%) | catalogued as rs1332074006; called by muse, mutect2
- SLC4A1 | c.237G>A p.A79= | Silent (SNP) | VAF 42/378 reads (11%) | catalogued as rs371489580; called by muse, mutect2, varscan2
- SLC6A7 | c.630T>A p.P210= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- SLC8A2 | c.324C>A p.T108= | Silent (SNP) | VAF 64/484 reads (13%) | called by muse, mutect2, varscan2
- SWT1 | c.810G>T p.L270= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100833552; called by muse, mutect2, varscan2
- TBX19 | c.684A>G p.V228= | Silent (SNP) | VAF 48/536 reads (9%) | catalogued as rs1398737771; called by muse, mutect2
- TBX4 | c.1360C>A p.R454= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- TENM2 | c.471T>A p.S157= | Silent (SNP) | VAF 62/690 reads (9%) | called by muse, mutect2
- TSEN34 | c.303A>T p.A101= | Silent (SNP) | VAF 43/322 reads (13%) | called by muse, mutect2, varscan2
- UGT2B7 | c.36A>T p.I12= | Silent (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- USP17L1 | c.981G>A p.G327= | Silent (SNP) | VAF 36/722 reads (5%) | called by muse, mutect2
- VEPH1 | c.1167G>T p.L389= | Silent (SNP) | VAF 13/168 reads (8%) | catalogued as COSV100747644; called by muse, mutect2
- YIPF5 | c.279A>G p.L93= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs986610993; called by muse, mutect2, varscan2
- ZNF280A | c.1224T>C p.D408= | Silent (SNP) | VAF 11/171 reads (6%) | called by muse, mutect2
- AC004801.4 | n.2622T>A | RNA (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- AGAP7P | n.959G>T | RNA (SNP) | VAF 24/546 reads (4%) | called by muse, mutect2
- AJAP1 | c.*5166C>G | 3'UTR (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- ANKRD20A8P | n.660C>A | RNA (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- BPI | c.-7C>A | 5'UTR (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- C16orf89 | c.-12C>T | 5'UTR (SNP) | VAF 25/372 reads (7%) | catalogued as rs769578777; called by muse, mutect2
- DNM3 | c.-11C>A | 5'UTR (SNP) | VAF 33/335 reads (10%) | called by muse, varscan2
- FAM183BP | n.252C>T | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- FOXG1 | chr14:28773432 C>G | 3'Flank (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- HMGA2 | c.250-36328A>T | Intron (SNP) | VAF 53/391 reads (14%) | called by muse, mutect2, varscan2
- IL7R | c.*28C>A | 3'UTR (SNP) | VAF 43/304 reads (14%) | called by muse, mutect2, varscan2
- IMPG1 | c.562+279A>G | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs1020937981; called by muse, varscan2
- KARS1 | c.-14G>T | 5'UTR (SNP) | VAF 62/480 reads (13%) | catalogued as COSV100093616; called by muse, mutect2, varscan2
- KLRK1 | c.-22G>T | 5'UTR (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- LTBP4 | chr19:40593145 A>G | 5'Flank (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- MLXIPL | c.*36G>T | 3'UTR (SNP) | VAF 28/262 reads (11%) | catalogued as rs1554592686; called by muse, mutect2
- MOXD1 | c.264+8897G>C | Intron (SNP) | VAF 14/331 reads (4%) | called by muse, mutect2
- MTMR8 | c.-15G>T | 5'UTR (SNP) | VAF 20/298 reads (7%) | catalogued as rs1489169248, COSV66395079; called by muse, mutect2
- NAP1L6P | n.387G>T | RNA (SNP) | VAF 39/504 reads (8%) | called by muse, mutect2
- NPAS2 | c.-23+734T>C | Intron (SNP) | VAF 21/301 reads (7%) | called by muse, mutect2
- OR2M1P | n.785C>A | RNA (SNP) | VAF 38/302 reads (13%) | called by muse, varscan2
- OTOAP1 | n.2176T>A | RNA (SNP) | VAF 24/501 reads (5%) | called by muse, mutect2
- PFKP | c.112+1637G>A | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- PKD1 | c.8791+11C>A | Intron (SNP) | VAF 26/313 reads (8%) | catalogued as rs764323671; called by muse, mutect2
- RBFOX1 | c.28-185142C>A | Intron (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- RBMX2 | c.-40C>A | 5'UTR (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- RGS11 | c.318+265G>C | Intron (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- TPH2 | c.*25C>A | 3'UTR (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- TSACC | c.-1G>T | 5'UTR (SNP) | VAF 28/287 reads (10%) | called by muse, mutect2
- UBR7 | c.*1091G>T | 3'UTR (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- UVSSA | c.*8700G>T | 3'UTR (SNP) | VAF 28/662 reads (4%) | called by muse, mutect2
